Gene-level copy-number profile of tumor specimen TCGA-AG-3587-01A from TCGA case TCGA-AG-3587, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 65.9 years (24,075 days).
Specimen TCGA-AG-3587-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.946b022d-ce44-4628-bdf3-cb2473c24f8d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3587-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/193efdf2-98c0-42cf-b681-4b8906d6fce9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 538; copy number 2: 4,530; copy number 3: 30,002; copy number 4: 18,363; copy number 5: 3,570; copy number 6: 984; copy number 7: 1,645; copy number 8: 184.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AG-3587-01): tumor purity 0.79, ploidy 3.54, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,829 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:62,460,940–63,779,336, 19 genes, copy number 7: DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 7: AL354719.1, SCAT8, GCNT1P4.
- chr7:137,381,037–138,118,305, 10 genes, copy number 8 (within-gene range 4–8): DGKI, AC090498.1, AC009245.1, CREB3L2, CREB3L2-AS1, AKR1D1, AC009263.1, AC024082.1, AC024082.2, RN7SKP223.
- chr7:154,544,169–154,547,285, 1 gene, copy number 8: AC024730.1.
- chr8:67,952,046–70,078,032, 31 genes, copy number 7 (within-gene range 6–7): PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P.
- chr8:75,120,409–145,066,685, 1,082 genes, copy number 7 (broad region; genes not listed).
- chr10:37,775,371–38,360,098, 21 genes, copy number 7 (within-gene range 3–7): AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4.
- chr10:38,250,442–38,250,603, 1 gene, copy number 7: AL117339.2.
- chr14:22,190,158–22,490,553, 38 genes, copy number 7: TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48.
- chr20:1,226,056–16,053,197, 257 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:15,552,157–16,770,062, 14 genes, copy number 7: AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR.
- chr20:30,484,925–33,023,703, 79 genes, copy number 8 (broad region; genes not listed).
- chr20:35,668,052–35,950,370, 10 genes, copy number 8 (within-gene range 5–8): NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P.
- chr20:38,098,414–38,923,024, 36 genes, copy number 8: RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P.
- chr20:39,932,922–41,124,487, 10 genes, copy number 7–8 (within-gene range 4–8): HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1.
- chr20:41,991,140–42,063,969, 3 genes, copy number 8: AL049812.2, AL049812.1, AL049812.3.
- chr20:42,968,743–45,348,424, 73 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr20:48,471,308–50,958,555, 67 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:52,972,358–54,269,542, 24 genes, copy number 7 (within-gene range 6–7): TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1.
- chr20:60,478,111–60,814,211, 4 genes, copy number 8: MIR4533, MIR548AG2, AL117372.1, AL139348.1.
- chr20:62,122,461–62,937,952, 46 genes, copy number 7 (within-gene range 5–7): LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1.

Autosomal genes at a single copy (total copy number 1): 535. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
